CCDI case PBBXYA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/5c6d10f9-cb5d-4caf-b376-a4a14955fad6

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 6.5 years (2,370 days).

Biospecimens (3 samples)
- Sample 0DKDBW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKDCA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKDDB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
